Gene-level copy-number profile of tumor specimen TCGA-AX-A1C7-01A from TCGA case TCGA-AX-A1C7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 77.2 years (28,198 days).
Specimen TCGA-AX-A1C7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.ef55b016-694d-4388-b285-9e531cc23915.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A1C7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/50798ce4-135d-4140-82d3-ba13cee05203

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 143; copy number 2: 12,420; copy number 3: 4,997; copy number 4: 32,628; copy number 5: 3,026; copy number 6: 2,456; copy number 7: 2,206; copy number 8: 1,473; copy number 9: 214; copy number 10: 73; copy number 11: 60; copy number 12: 30; copy number 13: 8; copy number 15: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A1C7-01A-11D-A134-01): tumor purity 0.94, ploidy 3.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,793,584–80,804,598, 34 genes (within-gene range 0–2): AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2, AC092376.2, AC092376.3, AC092376.1, RNA5SP431, AC084064.1, MAF, AC009159.2, AC009159.3, AC009159.1, AC009159.4, LINC01229, MAFTRR, LINC01228, AC092130.1, AC022166.1, AC105411.1, AC022166.2, DYNLRB2, AC108097.1, LINC01227, CDYL2, AC092332.1, AC099313.1.
- chr18:8,133,203–8,155,070, 2 genes: AC006566.2, AC006566.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 425 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:45,388,680–45,612,165, 2 genes, copy number 10 (within-gene range 8–10): SRBD1, RN7SL414P.
- chr2:45,674,701–45,675,476, 1 gene, copy number 10: PRKCE-AS1.
- chr2:101,962,056–102,711,355, 16 genes, copy number 9 (within-gene range 7–9): LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2.
- chr3:174,438,573–175,810,548, 1 gene, copy number 11 (within-gene range 7–13): NAALADL2.
- chr3:175,059,361–175,676,801, 8 genes, copy number 13 (within-gene range 7–13): EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1.
- chr6:30,363,112–30,914,106, 38 genes, copy number 10: UBQLN1P1, MICC, AL662873.1, TMPOP1, SUCLA2P1, RANP1, HLA-E, LINC02569, GNL1, PRR3, ABCF1, MIR877, PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640, GTF2H4.
- chr8:141,055,290–141,518,737, 20 genes, copy number 9: AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1.
- chr8:144,095,039–145,066,685, 67 genes, copy number 9 (broad region; genes not listed).
- chr11:61,615,036–62,426,724, 37 genes, copy number 11: RPLP0P2, AP002754.2, DAGLA, MYRF-AS1, MYRF, TMEM258, MIR611, FEN1, FADS2, FADS1, MIR1908, FADS3, MIR6746, RAB3IL1, RNU6-1243P, BEST1, FTH1, AP003733.3, AP003733.1, LINC02733, AP003733.2, AP002793.1, INCENP, EEF1DP8, SCGB1D1, SCGB2A1, AP003306.1, SCGB1D2, SCGB2A2, SCGB1D4, NPM1P35, AP003306.2, ASRGL1, RCC2P6, AP003064.1, SCGB1A1, AP003064.2.
- chr12:121,308,245–121,888,643, 20 genes, copy number 11: ANAPC5, AC048337.1, RNF34, KDM2B, MIR7107, KDM2B-DT, RNU6-1004P, ORAI1, MORN3, AC084018.3, TMEM120B, RHOF, LINC01089, AC084018.1, AC084018.2, SETD1B, HPD, AC079360.1, AC069503.3, AC069503.5.
- chr17:39,057,019–39,402,523, 11 genes, copy number 10 (within-gene range 7–10): RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20.
- chr20:10,612,861–11,301,525, 11 genes, copy number 10 (within-gene range 8–10): AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1.
- chr20:13,849,247–16,053,197, 3 genes, copy number 11–12 (within-gene range 5–12): SEL1L2, RNU6-278P, MACROD2.
- chr20:14,547,184–18,561,415, 70 genes, copy number 9–15 (within-gene range 8–15) (broad region; genes not listed).
- chr20:20,738,433–20,972,562, 3 genes, copy number 10: RN7SL607P, MRPS11P1, AL133465.1.
- chr20:31,341,371–33,443,763, 85 genes, copy number 9 (broad region; genes not listed).
- chr20:35,002,404–35,216,240, 7 genes, copy number 10 (within-gene range 6–10): TRPC4AP, RNU6-407P, EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483.
- chr20:44,106,590–44,311,202, 6 genes, copy number 9: JPH2, AL035447.1, OSER1, OSER1-DT, GDAP1L1, FITM2.
- chr20:46,364,551–47,188,844, 19 genes, copy number 9 (within-gene range 6–9): AL133227.1, ELMO2, ZNF663P, AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1.

Autosomal genes at a single copy (total copy number 1): 143. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
